Gene-level copy-number profile of tumor specimen C3N-06993-01 from CPTAC case C3N-06993, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.7 years (25,808 days).
Specimen C3N-06993-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ef83ba31-49ff-4a9b-af1a-6cc8633c778b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06993-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/5d6014c4-38b9-4a8f-9e7f-54fd7c4af274

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 13,837; copy number 2: 36,786; copy number 3: 6,224; copy number 4: 1,198; copy number 5: 262.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:125,734,295–125,748,098, 2 genes: OR7E53P, OR7E97P.
- chr4:189,764,391–190,092,279, 23 genes: FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:7,926,337–7,952,413, 2 genes: ZNF705B, DEFB108A.
- chr8:12,182,096–12,418,090, 14 genes (within-gene range 0–1): FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P.
- chr11:89,944,035–90,087,131, 16 genes: AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr16:90,056,566–90,222,851, 8 genes: PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–1): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr21:9,068,361–9,376,645, 6 genes: TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 262 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:134,284,500–140,404,433, 110 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:140,404,058–142,892,743, 140 genes, copy number 5 (broad region; genes not listed).
- chr15:90,529,923–90,853,608, 12 genes, copy number 5: CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1.

Autosomal genes at a single copy (total copy number 1): 13,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
